Somatic mutation profile of tumor specimen TCGA-FG-A713-01A (aliquot TCGA-FG-A713-01A-11D-A32B-08) from TCGA case TCGA-FG-A713, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 74.6 years (27,232 days).
Specimen TCGA-FG-A713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 069c0fc1-8503-49c0-99b3-5273b2c8e991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A713-10A (Blood Derived Normal), aliquot TCGA-FG-A713-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c202be2e-d06e-4bf6-8854-162c514f5b41

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ACACB | c.7144G>T p.V2382L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100622959; called by muse, mutect2, varscan2
- ADGRG7 | c.1940C>G p.S647W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99841095; called by muse, mutect2, varscan2
- ALMS1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100042612; called by muse, mutect2, varscan2
- ATRX | c.594+1G>A p.X198_splice | Splice Site (SNP) | VAF 16/85 reads (19%) | catalogued as COSV64870251; called by muse, mutect2, varscan2
- CIC | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50570806; called by muse, mutect2, varscan2
- CNOT4 | c.1388A>G p.N463S (on ENST00000315544 / NM_001190848.1; = p.N460S on NM_013316.4) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.099); catalogued as rs745842800, COSV100210948; called by muse, mutect2, varscan2
- FEZ1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99630697; called by muse, mutect2, varscan2
- HECTD1 | c.2380A>G p.R794G | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101237404; called by muse, mutect2, varscan2
- LRRIQ1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1487507072, COSV101280503; called by muse, mutect2, varscan2
- MED16 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV54132072, COSV99515702; called by muse, mutect2, varscan2
- PCDH7 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1211964760, COSV100688356; called by muse, mutect2
- PRAMEF4 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99339865; called by muse, mutect2, varscan2
- PRSS55 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756348631, COSV60807707, COSV60809623; called by muse, mutect2
- RBM7 | c.573A>C p.Q191H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100972167; called by muse, mutect2, varscan2
- SLC6A12 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759619929, COSV100675120; called by muse, mutect2, varscan2
- TNFRSF9 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399281402, COSV101097333, COSV66348694; called by muse, mutect2, varscan2
- EPC2 | c.258del p.Y86* | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
- TUBA1A | c.144_147del p.F49Tfs*19 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | called by mutect2, pindel, varscan2
- CNMD | c.435C>T p.G145= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs746623684, COSV65032769; called by muse, mutect2, varscan2
- DAAM1 | c.1596G>A p.S532= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs773988645, COSV100658438; called by muse, mutect2, varscan2
- GREM1 | c.267G>A p.L89= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100277961; called by muse, mutect2, varscan2
- LTBP3 | c.960C>T p.P320= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1369667378, COSV100099739; called by muse, mutect2, varscan2
- PLXND1 | c.1668G>C p.G556= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs919118961, COSV100139817; called by muse, mutect2, varscan2
- TAC3 | c.13C>T p.L5= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100269872; called by muse, mutect2
- TAS1R1 | c.2391G>T p.L797= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100039687; called by muse, mutect2, varscan2
